Somatic mutation profile of tumor specimen CDDP-ACM1-TTP1-A (aliquot CDDP-ACM1-TTP1-A-1-0-D-A572-36) from CDDP_EAGLE case CDDP-ACM1, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70 years.
Specimen CDDP-ACM1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2d5e20f-2a55-4151-ae8e-b53085077895.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACM1-NB1-A (Blood Derived Normal), aliquot CDDP-ACM1-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96bc33ab-5043-4801-9548-6c4493e621a8

The open-access MAF lists 29 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, RNA 3, 3'UTR 1, Nonsense Mutation 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.402T>G p.F134L | Missense Mutation (SNP) | VAF 150/400 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52723236, COSV52814502, COSV52902300; called by muse, mutect2, varscan2
- AMOTL2 | c.2054T>G p.L685R | Missense Mutation (SNP) | VAF 213/788 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.255); catalogued as COSV51438122; called by muse, mutect2, varscan2
- ATRX | c.6678G>C p.R2226S | Missense Mutation (SNP) | VAF 100/483 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV64873079; called by muse, mutect2, varscan2
- CD109 | c.2746C>T p.R916W | Missense Mutation (SNP) | VAF 88/390 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749134372, COSV54646604; called by muse, mutect2, varscan2
- COL5A1 | c.2791G>A p.G931S | Missense Mutation (SNP) | VAF 86/297 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65666435; called by muse, mutect2, varscan2
- CTRB2 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 59/320 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs537336864, COSV57315396; called by muse, mutect2, varscan2
- DOCK7 | c.5149C>T p.L1717F (on ENST00000635253 / NM_001367561.1; = p.L1686F on NM_033407.3) | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51998628; called by muse, mutect2, varscan2
- DPY19L3 | c.706C>G p.Q236E | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.083); catalogued as COSV60475163; called by muse, varscan2
- GJD2 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 107/363 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51747502; called by muse, mutect2, varscan2
- LRRCC1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs753887030, COSV64482879; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.515A>C p.D172A | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57963437; called by muse, mutect2, varscan2
- SOSTDC1 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61049083; called by muse, mutect2, varscan2
- TFPT | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as rs142642138, COSV100338242; called by muse, mutect2, varscan2
- UNC13A | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 105/317 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53190584; called by muse, mutect2, varscan2
- ZNRF2 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV59910573; called by muse, mutect2, varscan2
- ARID1A | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2
- PRUNE1 | c.24T>A p.C8* | Nonsense Mutation (SNP) | VAF 35/624 reads (6%) | called by muse, mutect2
- ATR | c.5419C>T p.L1807= | Silent (SNP) | VAF 85/385 reads (22%) | catalogued as COSV63384825; called by muse, mutect2, varscan2
- CCT7 | c.426C>G p.T142= | Silent (SNP) | VAF 54/417 reads (13%) | catalogued as rs199840482, COSV57821536; called by muse, mutect2, varscan2
- FAM133B | c.102G>T p.L34= | Silent (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- NEURL1 | c.273C>T p.N91= | Silent (SNP) | VAF 58/390 reads (15%) | catalogued as rs200896969; called by muse, mutect2, varscan2
- SEMA5B | c.3264G>A p.P1088= | Silent (SNP) | VAF 72/243 reads (30%) | catalogued as rs753033321, COSV52098030; called by muse, mutect2, varscan2
- SLC45A4 | c.966C>T p.P322= (on ENST00000517878 / NM_001286646.2; = p.P271= on NM_001080431.2) | Silent (SNP) | VAF 80/283 reads (28%) | catalogued as rs144027256, COSV99196710; called by muse, mutect2, varscan2
- GUSBP10 | n.332G>A | RNA (SNP) | VAF 50/658 reads (8%) | called by muse, mutect2
- H2BC15 | c.377+2566C>T | Intron (SNP) | VAF 64/221 reads (29%) | called by muse, varscan2
- KNCN | c.*312T>A | 3'UTR (SNP) | VAF 166/389 reads (43%) | called by muse, mutect2, varscan2
- MAP3K13 | c.-135A>C | 5'UTR (SNP) | VAF 14/293 reads (5%) | called by muse, mutect2
- MIR612 | n.98_100dup | RNA (INS) | VAF 20/120 reads (17%) | called by mutect2, pindel, varscan2
- SNORA9 | n.77G>T | RNA (SNP) | VAF 48/354 reads (14%) | called by muse, mutect2, varscan2
